Surgical pathology report (de-identified scan), TCGA case TCGA-IM-A3U2, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Miami, specimen TCGA-IM-A3U2-01A (Primary Tumor).

[page 1 of 5]
AGE/SEX: 1/
REG

Addendum #1

C. TOTAL THYROID WITH PARATRACHEAL NODE DISSECTION:

Congo Red stain shows focal birefringency under polarized light.

SPECIMEN ID:

- A. MUSCLE - LATISMA R/O PAPILLARY CARCINOMA FS,
- B. LYMPH NODE - RIGHT MODIFIED NECK DISSECTION LEVEL 1-4,
- C. THYROID GLAND - TOTAL THYROID WITH PARATRACHEAL NODE DISSECTION,
- D. LYMPH NODE - LEFT LEVEL 6 NODE DISSECTION,
- E. LYMPH NODE - LEFT NECK DISSECTION L 2,3,4

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call and
return the report to us by mail.

ICD-O-3
path: carcinoma, papillary,
diffuse sclerosing 8390/3
CQCF: carcinoma, papillary, tall cell
8344/3
Site: thyroid, NOS
C73.9 4-10-12
20

[page 2 of 5]
• • •

A. LATISMA:

Fibroadipose and skeletal muscle.

B. RIGHT MODIFIED NECK DISSECTION LEVEL 1-4:

Twenty-five out of thirty-three lymph nodes (25/33) positive for METASTATIC PAPILLARY THYROID CARCINOMA, largest focus 3.0 cm.

Extranodal extension is present - largest tumor size: 3.0 cm; adjacent to jugular.

Salivary gland is present.

C. TOTAL THYROID WITH PARATRACHEAL NODE DISSECTION (22 GRAMS):

PAPILLARY THYROID CARCINOMA, diffuse sclerosing variant, with tall cell and follicular cell variant, 4.3 cm in right lobe.

Multifocal extra thyroidal extension.

There is lymphovascular invasion present with extensive intrathyroidal spread with multiple satellite tumor nodules in the left lobe, measuring up to 0.9 cm.

No parathyroid gland present.

No lymph nodes present.

AJCC Classification edition): pT3 N1b Mx (INCLUDING ALL SPECIMENS)

See tumor summary.

D. LEFT LEVEL 6 NODE DISSECTION:

METASTATIC PAPILLARY THYROID CARCINOMA in four out of four (4/4).

Largest tumor size is 1.9 cm.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 3 of 5]
*** FINAL DIAGNOSIS *** (Continued)

Extranodal extension is present.

E. LEFT NECK DISSECTION L 2,3,4:

METASTATIC PAPILLARY THYROID CARCINOMA to two out of twenty-six (2/26) lymph nodes.

Largest tumor size is 1.5 cm.

Pathology Cancer Case Summary:

Procedure: Total thyroidectomy with bilateral neck dissection

Received: In formalin

Specimen Integrity: Intact

Specimen Size:

Right lobe: 4.3 x 3.5 x 2.5

Left lobe: 3.5 x 2.5 x 1.2

Right neck dissection: 11.0 x 7.0 x 1.5 cm

Left neck dissection: 8.0 x 3.5 x 1.5

Additional dimensions: Left level 6 node dissection: 3.0 x 2.5 x 1.2 cm

Tumor Focality: Multifocal and bilateral

Dominant Tumor:

Tumor Size:

Greatest dimension: 4.3

Additional dimensions: 3.5 x 2.5

Histologic Type: Papillary carcinoma with intrathyroidal spread to left lobe, diffuse sclerosing variant with follicular variant, tall cell variant

Architecture: Follicular

Cytomorphology: Tall cell

Margins: Margins involved by carcinoma, multiple sites

Tumor Capsule: None

Tumor Capsular Invasion: Indeterminate

Lymph-Vascular Invasion: Present and extensive (4 or more vessels) bilateral

Perineural Invasion: Not identified

Pathologic Staging (pTNM): Primary Tumor (pT): pT3: Tumor more than 4.0 cm limited to thyroid or any tumor with minimal extrathyroid extension (eg, extension to sternothyroid muscle or perithyroid soft tissue)

Regional Lymph Nodes (pN): pN1b: Metastases to unilateral, bilateral or contralateral

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 4 of 5]
***** FINAL DIAGNOSIS *** (Continued)**

cervical (Levels I, II, III, IV, V) or retropharyngeal or superior mediastinal lymph nodes (VII) Number examined: 63; Number involved: 31
Distant Metastasis (pM): Not applicable

CLINICAL HISTORY-

PRE-OP DX: THYROID CARCINOMA
PROCEDURE: TOTAL THYROIDECTOMY
RELEVANT CLINICAL HX: NONE PROVIDED

GROSS DESCRIPTION:

A. Received fresh labeled "Platysma" an irregularly shaped soft tissue fragment measuring 1.2 x 0.6 x 0.3 cm. The specimen is submitted in toto in one cassette for frozen section.

B. Received in formalin labeled "Right modified neck dissection level 1-4" consists of a yellow-tan and irregularly shaped fibrofatty tissue measuring 11.0 x 7.0 x 3.0 cm. On section reveals a yellow-tan salivary gland measuring 3.5 x 2.5 x 1.5 cm. On section reveals homogeneous light tan cut surface to be unremarkable. On section reveal thirty-one lymph nodes ranging in size from 4.5 x 3.5 x 3.0 cm to 0.2 x 0.2 x 0.1 cm. Attached to the bigger lymph node is a jugular vein measuring 3.0 cm in length by 0.8 cm in diameter. The specimen is submitted in ten cassettes as follows:

Cassettes #1-4	Six lymph nodes in toto per cassette
Cassette #5	Four lymph nodes in toto
Cassettes#6&7	One lymph node per cassette
Cassettes#8&9	Largest nodule bisected in relation with jugular vein
Cassette #10	Salivary gland

C. Received in formalin labeled "Total thyroid" is a paratracheal node dissection. The specimen consists of a total thyroidectomy weighing 22 grams and measuring right lobe from superior to inferior 4.3 cm from lateral to medial 3.5 cm and anterior to posterior 2.5 cm, left lobe measuring from superior to inferior 3.5 cm, from lateral to medial 2.5 cm and anterior to posterior 1.2 cm. The right lobe is totally distorted with the firm to hard sensation. The resection margin is inked black. No parathyroid gland is present. On section of the right lobe reveal light tan to yellow

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call / and
return the report to us by mail.

[page 5 of 5]
GROSS DESCRIPTION: (Continued)

from superior to inferior pole, firm to hard sensation with the central area calcified. The right lobe parenchyma shows papillary cut surfaces. This lobe reveal diffusely ill-defined tumor invading capsule. On section of the left lobe reveal multiple light tan nodule ranging in size from 1.2 x 1.0 x 1.0 cm to 0.9 cm in greatest dimension. The specimen is submitted in toto in twenty cassettes as follows:

Cassette #1 Perpendicular section superior right pole
Cassette #2 Perpendicular section inferior right pole
Cassettes #3-13 Right lobe from superior to inferior
Cassette #14 Perpendicular section superior left pole
Cassette #15 Perpendicular section inferior left pole
Cassettes #16-20 From superior to inferior left lobe

Note: Sample of this specimen was given to tissue bank.

- D. Received in formalin labeled "Left level 6 node dissection" consists of a dark brown and irregularly shaped soft tissue measuring 3.0 x 2.5 x 1.2 cm. On section reveal four lymph nodes ranging in size from 2.0 x 1.5 x 1.5 cm to 0.3 x 0.2 x 0.2 cm. The specimen is submitted in two cassettes as follows:

Cassette #1 Three lymph nodes in toto
Cassette #2 One lymph node

- E. Received in formalin labeled "Left neck dissection - level 2,3,4" consists of a yellow-tan and irregularly shaped soft tissue fragment measuring 8.0 x 3.5 x 1.5 cm. On section reveal twenty-eight lymph nodes ranging in size from 1.8 x 1.5 x 1.5 cm. To 0.2 x 0.2 x 0.1 cm. The specimen is submitted in five cassettes as follows:

Cassettes #1-4 Six lymph nodes in toto per cassette
Cassettes #5 Four lymph nodes

OPERATING ROOM CONSULT (FS-CYT)**A. LATISMA:**

Skeletal muscle and lymphoid tissue, no tumor seen.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [redacted] and
return the report to us by mail.

PPAA Discrepancy		

Source: NCI Genomic Data Commons file da2ceef7-8969-4f04-9a7c-c11618e4295e (TCGA-IM-A3U2.77A0F952-13A6-44CF-81DB-67E4C21A530A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).